ALCHEMIST case ALCH-ABBR — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/91c37870-5791-48cf-b532-1a391a029acf

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 81.8 years (29,875 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-ABBR-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-ABBR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-ABBR-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 30; Percent normal cells: 10; Percent necrosis: 20; Percent stromal cells: 40; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 0.
  Slide ALCH-ABBR-TTP1-A-1-0-S2: Section location: Bottom; Percent tumor cells: 20; Percent tumor nuclei: 20; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 70; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 60; Percent neutrophil infiltration: 10.
